Somatic mutation profile of tumor specimen 0DRZIU from CCDI case PBCGBB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 5.6 years (2,037 days).
Specimen 0DRZIU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56bc1694-6240-40e4-8136-d4b8832e8e97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRZJD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e10020b7-f9e5-41f5-87f3-08552788e2fb

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 3, Silent 2, 3'UTR 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 379/430 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PPM1D | c.1535dup p.N512Kfs*16 | Frame Shift Ins (INS) | VAF 500/1465 reads (34%) | catalogued as rs763475304; called by mutect2, varscan2
- COL11A2 | c.1520C>T p.P507L (on ENST00000341947 / NM_080680.3; = p.P400L on NM_080679.2) | Missense Mutation (SNP) | VAF 20/612 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); called by muse, mutect2
- KMT5B | c.2312G>C p.G771A | Missense Mutation (SNP) | VAF 429/962 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- PTGS2 | c.705T>A p.D235E | Missense Mutation (SNP) | VAF 22/868 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.437); called by muse, mutect2
- SPON2 | c.122C>A p.A41D | Missense Mutation (SNP) | VAF 186/333 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TMEM30A | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 206/512 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- UNC13A | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 37/307 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF227 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 191/499 reads (38%) | called by muse, mutect2, varscan2
- APOB | c.9336G>A p.E3112= | Silent (SNP) | VAF 216/500 reads (43%) | catalogued as rs750547432, COSV51929835; called by muse, mutect2, varscan2
- DCAF12 | c.729C>T p.I243= | Silent (SNP) | VAF 48/603 reads (8%) | called by muse, mutect2
- ARIH2 | c.770+97G>T | Intron (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- SATB1 | c.1779+686G>A | Intron (SNP) | VAF 69/400 reads (17%) | catalogued as rs765516068; called by muse, mutect2, varscan2
- STK32A | c.*23G>A | 3'UTR (SNP) | VAF 110/514 reads (21%) | catalogued as rs1374134757; called by muse, mutect2, varscan2
- SYCE1 | c.197-88G>A | Intron (SNP) | VAF 40/208 reads (19%) | called by muse, mutect2, varscan2
